Gene-level copy-number profile of tumor specimen C3N-02240-03 from CPTAC case C3N-02240, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 49.8 years (18,199 days).
Specimen C3N-02240-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4c1b8b2e-d83c-489a-a383-0c67630e20d9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02240-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/96e5fbde-d002-4cc5-8f86-bd8ae63cf515

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 3,226; copy number 2: 35,311; copy number 3: 15,344; copy number 4: 4,825; copy number 5: 3; copy number 6: 2; copy number 7: 4; copy number 10: 115; copy number 16: 21; copy number 17: 57; copy number 20: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 198 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:55,602,360–55,607,645, 1 gene, copy number 7: OR4C11.
- chr14:35,044,907–42,989,483, 111 genes, copy number 10–17 (broad region; genes not listed).
- chr14:44,763,153–45,074,431, 9 genes, copy number 17: LINC02302, DOCK11P1, AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3, KLHL28, TOGARAM1.
- chr22:18,400,407–18,512,187, 4 genes, copy number 7–16: PPP1R26P3, FAM230A, AC023490.2, FAM247B.
- chr22:25,561,117–25,564,719, 1 gene, copy number 20: AL022329.1.
- chr22:31,488,688–31,618,588, 1 gene, copy number 10 (within-gene range 2–10): SFI1.
- chr22:31,521,199–35,087,387, 71 genes, copy number 10–16 (within-gene range 2–16) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,355. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
